Surgical pathology report (de-identified scan), TCGA case TCGA-27-2519, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Milan - Italy, Fondazione IRCCS Instituto Neuroligico C. Besta, specimen TCGA-27-2519-01A (Primary Tumor).

TCGA-27-2519

Ref. Number

Gender

Birth date

Tumor site

Right frontal

Histological diagnosis

Glioblastoma multiforme

Source: NCI Genomic Data Commons file 928b057a-3154-4e46-8b6b-bd3f5648d89c (TCGA-27-2519.FD339D84-0063-4F89-B81D-6C0CFF9C28F5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).